Gene-level copy-number profile of tumor specimen HCM-CSHL-0654-C26-06A from HCMI case HCM-CSHL-0654-C26, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Unknown primary site; Tumor grade: G3; Age at diagnosis: 70.6 years (25,800 days).
Specimen HCM-CSHL-0654-C26-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 28d5802b-82ed-4aa8-8776-4df0453078fc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0654-C26-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/dc310784-5248-405f-a113-68dc7e023e82

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1,000; copy number 2: 18,314; copy number 3: 23,897; copy number 4: 15,569; copy number 5: 76; copy number 6: 23; copy number 7: 3; copy number 12: 2; copy number 46: 1; copy number 217: 1; copy number 244: 1; copy number 247: 1; copy number 293: 13.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr11:55,602,360–55,686,160, 7 genes: OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:118,923,557–118,982,875, 3 genes, copy number 7: TNFRSF11B, RNU6-12P, AC107953.1.
- chr8:124,044,395–124,171,522, 1 gene, copy number 217 (within-gene range 3–217): FER1L6-AS2.
- chr11:34,742,906–35,620,865, 15 genes, copy number 244–293: AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1.
- chr13:109,478,739–109,786,583, 3 genes, copy number 12–46 (within-gene range 4–46): AL163541.1, LINC00676, IRS2.

Autosomal genes at a single copy (total copy number 1): 178. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
